Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAEH, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAEH-01A (Primary Tumor).

[page 1 of 2]
LINICAL DIAGNOSIS: HCC

Specimen : Liver

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Left hemihepatectomy

Organs: Liver (21.8 x 12.5 x 4.0 cm, 398.0 gm)

Lesion: A well-defined yellow to tan nodule (4.0 x 3.0 x 5.8 cm)

Cut surface: A well defined yellow to tan firm and solid nodule (expanding nodular type)

Resection margin: Not involved grossly (safety margin: 1.8 cm)

Others:

Satellite nodule: No

Remaining parenchyma: Stage 2 fibrosis

Gross photo: Present

Blocks

TB, T1-4, mass x 5

NB, L, liver parenchyma x 2

RM, resection margin x 1

GB, gallbladder x 1

ICD-O 3
Carcinoma, hepatocellular NOS
8170/3
Site: Liver C22.0
9/5/20/14

MICROSCOPIC:

Tumor type: Hepatocellular carcinoma

Histologic grade (Edmondson-Steiner grade for hepatocellular carcinoma):

The worst differentiation: II

The major differentiation: I

Histologic type: Trabecular and pseudoglandular

Cell type: Hepatic

Fatty change: No

Fibrous capsule formation: Partial

Capsular infiltration: Yes

Septum formation: Yes

Surgical resection margin invasion: No (safety margin - 1.8 cm)

Serosal invasion: No

Portal vein invasion: No

Microvessel invasion: Yes

Intrahepatic metastasis: Unknown

Multicentric occurrence: Unknown

NOT reported. Gross:

NOT reported. Gross:

liver,ectomy,Hepatocellular carcinoma

[page 2 of 2]
T56000, P10, M81703

gallbladder,ectomy,chronic cholecystitis

T57000, P10, M43005

lymph node,ectomy,Reactive hyperplasia

T08000, P10, M72200

DIAGNOSIS:

Liver, left, hemihepatectomy:

Hepatocellular carcinoma, well differentiated

Gallbladder, cholecystectomy:

Chronic cholecystitis

Lymph node, adjacent to gallbladder, cholecystectomy:

Reactive hyperplasia (0/1)

Suggestion :

Source: NCI Genomic Data Commons file 23ebd5d0-1a18-4490-9b2d-f2ec75bd4245 (TCGA-DD-AAEH.D6F3E1F8-27F3-47F9-88CC-F4145C983073.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).